Somatic mutation profile of tumor specimen TCGA-50-6592-01A (aliquot TCGA-50-6592-01A-11D-1753-08) from TCGA case TCGA-50-6592, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.7 years (26,191 days).
Specimen TCGA-50-6592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9e30476-a9de-4dfa-8e62-75aaee9847d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6592-11A (Solid Tissue Normal), aliquot TCGA-50-6592-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c55bd532-2a60-4066-9be0-5f6d1e54cb05

The open-access MAF lists 311 somatic variants for this specimen: 242 protein-altering or splice-affecting, 62 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 62, Nonsense Mutation 18, Frame Shift Del 8, Splice Site 6, RNA 5, Frame Shift Ins 2, In Frame Del 1, Translation Start Site 1, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 40/170 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1057519934, COSV55876538, COSV55894288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV52212099; called by muse, mutect2, varscan2
- ABCC9 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV53986005; called by muse, mutect2, varscan2
- ABCC9 | c.617A>T p.E206V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53986021; called by muse, mutect2, varscan2
- ABCC9 | c.143-1G>T p.X48_splice | Splice Site (SNP) | VAF 14/113 reads (12%) | catalogued as COSV53986038; called by muse, mutect2, varscan2
- AC245033.1 | c.154+1G>A p.X52_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV55621537; called by muse, varscan2
- ADAMTS12 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV61279530; called by muse, mutect2, varscan2
- ADAMTS20 | c.4689C>G p.I1563M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV67131852, COSV67139303; called by muse, mutect2, varscan2
- ADAMTSL2 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV63206241; called by muse, mutect2, varscan2
- ADCY10 | c.2259A>T p.Q753H | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63244883; called by muse, mutect2, varscan2
- ADCY2 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV57900288; called by muse, mutect2
- AFG3L2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs748957187, COSV52317389; called by muse, mutect2
- AGXT2 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV51491167, COSV99183952; called by muse, mutect2
- AKR1C3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs35575889, CM109906; called by muse, mutect2, varscan2
- AKT3 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55632894; called by muse, mutect2, varscan2
- ALOX15 | c.1641+1G>T p.X547_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as rs1165144199, COSV53400627; called by muse, varscan2
- AMY2B | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 41/407 reads (10%) | catalogued as COSV63717069; called by muse, mutect2, varscan2
- ANK2 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52158801, COSV52188396; called by muse, mutect2, varscan2
- ANKRD12 | c.1738C>G p.L580V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.212); catalogued as COSV50848804; called by muse, mutect2, varscan2
- ANKRD35 | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV62911578; called by muse, mutect2, varscan2
- ANKRD7 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV54556060, COSV54556529; called by muse, mutect2, varscan2
- ANKZF1 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1053019834, COSV55478828; called by muse, mutect2
- APBB3 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as COSV100020999, COSV60054137; called by muse, mutect2, varscan2
- AQP4 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV67219432; called by muse, mutect2
- ARAP2 | c.3408A>G p.I1136M | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58292121; called by muse, mutect2
- ARHGEF6 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51695956; called by muse, mutect2, varscan2
- ARID2 | c.4925G>T p.W1642L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.33); catalogued as rs773280858, COSV57614546; called by muse, varscan2
- ARSJ | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59536886, COSV59537108; called by muse, mutect2, varscan2
- ASAP2 | c.2084A>T p.H695L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.136); catalogued as COSV55638653; called by muse, mutect2
- ASB5 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56674375; called by muse, mutect2, varscan2
- BPTF | c.6338C>T p.T2113I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58846684; called by muse, mutect2, varscan2
- BTBD2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55310642; called by muse, mutect2, varscan2
- C10orf71 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV60513242; called by muse, mutect2, varscan2
- C7 | c.1399A>C p.T467P | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV57480988; called by muse, mutect2, varscan2
- CAD | c.4921C>T p.H1641Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.995); catalogued as rs1176125731, COSV53031831; called by muse, mutect2, varscan2
- CDC16 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV52961893; called by muse, mutect2, varscan2
- CDH15 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV57023574; called by muse, mutect2, varscan2
- CDH5 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200378924, COSV58515664; called by muse, mutect2, varscan2
- CEACAM8 | c.878A>T p.N293I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs764185114, COSV54991812; called by muse, mutect2, varscan2
- CEMIP2 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as COSV65489537; called by muse, mutect2, varscan2
- CLCA4 | c.208dup p.R70Kfs*13 | Frame Shift Ins (INS) | VAF 17/177 reads (10%) | catalogued as rs148031684; called by mutect2, pindel
- CMAS | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57557548; called by muse, mutect2, varscan2
- CNOT10 | c.1859A>G p.N620S | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.038); catalogued as COSV59395283; called by muse, mutect2
- CNTN1 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV61639528, COSV61645691; called by muse, mutect2, varscan2
- COL15A1 | c.671T>A p.V224E | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV66649168; called by muse, mutect2, varscan2
- COMP | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1478847238, COSV55876562; called by muse, mutect2, varscan2
- CPT1A | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55761008; called by muse, mutect2, varscan2
- CPZ | c.758C>A p.A253E (on ENST00000360986 / NM_001014447.3; = p.A242E on NM_003652.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV59923681, COSV59926105; called by muse, mutect2, varscan2
- CREB3L2 | c.45C>A p.D15E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100382317; called by muse, mutect2, varscan2
- CSF2RB | c.2459G>A p.G820D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53260974; called by muse, mutect2, varscan2
- CSF3R | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58966869; called by muse, mutect2
- CSMD1 | c.6036T>A p.G2012= (on ENST00000520002; = p.G2011= on NM_033225.6) | Splice Region (SNP) | VAF 20/119 reads (17%) | catalogued as COSV59382456; called by muse, varscan2
- CSMD3 | c.1946C>A p.S649Y (on ENST00000297405 / NM_001363185.1; = p.S545Y on NM_052900.3) | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52317597; called by muse, mutect2, varscan2
- DAPK1 | c.640G>C p.A214P | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV63788508, COSV63791956; called by muse, mutect2, varscan2
- DCAF7 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60408724; called by muse, mutect2, varscan2
- DGKG | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148285460; called by muse, mutect2, varscan2
- DGKG | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53972678; called by muse, mutect2
- DNAH7 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV56786135; called by muse, mutect2, varscan2
- DOP1B | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV67696123; called by muse, mutect2, varscan2
- DSCAML1 | c.4613-1G>A p.X1538_splice (on ENST00000321322; = p.X1478_splice on NM_020693.4) | Splice Site (SNP) | VAF 12/68 reads (18%) | catalogued as COSV58402629; called by muse, mutect2, varscan2
- EEF1A2 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53208282; called by muse, mutect2, varscan2
- EIF4E2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV51473380; called by muse, mutect2, varscan2
- EMSY | c.3583G>T p.A1195S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV58265946; called by muse, mutect2, varscan2
- ENAM | c.3099C>G p.I1033M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV68537030; called by muse, mutect2, varscan2
- EPHA4 | c.2461G>T p.G821W | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025973, COSV56044090; called by muse, mutect2, varscan2
- FAM171B | c.1537A>G p.R513G | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.629); catalogued as COSV59000280, COSV59008673; called by muse, mutect2, varscan2
- FAM3C | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV63436563; called by muse, mutect2
- FARSB | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56052550; called by muse, mutect2, varscan2
- FIGN | c.225T>G p.Y75* | Nonsense Mutation (SNP) | VAF 7/174 reads (4%) | catalogued as COSV60771792; called by muse, mutect2
- FLNA | c.3882G>T p.K1294N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV61051597; called by muse, mutect2, varscan2
- FLNA | c.2836G>T p.G946C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61051609; called by muse, mutect2, varscan2
- FNDC3B | c.3227C>G p.T1076R | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV61041819, COSV61049746; called by muse, mutect2, varscan2
- FRMD7 | c.243T>A p.F81L | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53748833; called by muse, mutect2, varscan2
- GFRA1 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62610676; called by muse, mutect2
- GLCE | c.1749C>G p.I583M | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55948458; called by muse, mutect2, varscan2
- GNG11 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV50350521; called by muse, mutect2, varscan2
- GOSR2 | c.180G>T p.Q60H (on ENST00000393456 / NM_001321134.1; = p.Q78H on NM_004287.5) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV99846290; called by muse, mutect2
- GOSR2 | c.181C>T p.H61Y (on ENST00000393456 / NM_001321134.1; = p.H79Y on NM_004287.5) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1568171907, COSV99846297; ClinVar: uncertain significance; called by muse, mutect2
- GP5 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV59880171, COSV59880628; called by muse, mutect2, varscan2
- GPD2 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100133580, COSV60097010; called by muse, mutect2, varscan2
- GPRC6A | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59955919, COSV59956676; called by muse, varscan2
- GREB1 | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336517626, COSV52191572; called by muse, mutect2
- GRIK5 | c.1180A>T p.N394Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV99491402; called by muse, mutect2, varscan2
- GRIN2B | c.656A>T p.Q219L | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV74207839; called by muse, mutect2, varscan2
- GSDMC | c.1120G>C p.G374R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778432458, COSV52699307; called by muse, mutect2, varscan2
- GSTCD | c.1346G>T p.C449F (on ENST00000360505 / NM_001031720.3; = p.C362F on NM_024751.3) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853882; called by muse, mutect2, varscan2
- GTPBP3 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1371652885, COSV61413621, COSV61414981; called by muse, mutect2, varscan2
- H2AC20 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs782789995; called by pindel, varscan2
- HCN1 | c.1042G>C p.A348P | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HCN1 | c.625del p.D209Tfs*4 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as COSV100300372, COSV57538426; called by mutect2, pindel, varscan2
- HELB | c.3145C>G p.P1049A | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV56076230; called by muse, mutect2
- HIVEP2 | c.2817G>C p.K939N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50061618; called by muse, mutect2, varscan2
- HTR1E | c.81G>C p.M27I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59511038; called by muse, mutect2, varscan2
- IFNB1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.902); catalogued as rs769406949, COSV101207837; called by muse, mutect2, varscan2
- IGF2R | c.2748G>A p.W916* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | catalogued as COSV63629767; called by muse, mutect2
- INSIG2 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 27/185 reads (15%) | catalogued as COSV99830663; called by muse, mutect2, varscan2
- INSIG2 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99830667; called by muse, mutect2, varscan2
- IRAK1 | c.1328A>C p.E443A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV64113407; called by muse, mutect2
- IRGQ | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100338255; called by muse, mutect2
- IRGQ | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV60671485; called by muse, mutect2
- ISLR2 | c.1396C>G p.R466G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV62302795, COSV62303773; called by muse, mutect2
- ITIH2 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs929145287, COSV64435224; called by muse, mutect2, varscan2
- ITPR3 | c.692T>A p.L231Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.075); catalogued as COSV65414842; called by muse, mutect2, varscan2
- JAKMIP2 | c.923A>C p.E308A | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV54615420; called by muse, mutect2, varscan2
- KCND3 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as rs202110939, COSV56189657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ11 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100379225; called by muse, mutect2, varscan2
- KCNJ3 | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as COSV54536275; called by muse, mutect2, varscan2
- KLHL1 | c.2158T>A p.Y720N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64784037; called by muse, mutect2, varscan2
- KPNA3 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV55507276; called by muse, mutect2, varscan2
- LAMA1 | c.4543G>T p.G1515C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544355; called by muse, mutect2, varscan2
- LARP6 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs778158575, COSV54580631; called by muse, mutect2, varscan2
- LCE2A | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.785); catalogued as COSV64227173; called by muse, mutect2, varscan2
- LRFN1 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.085); catalogued as COSV50504893; called by muse, mutect2, varscan2
- LRP4 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.764); catalogued as COSV66138649; called by muse, mutect2, varscan2
- LRRC1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs769150436, COSV63824476, COSV63825227; called by muse, mutect2
- LTBP4 | c.3962G>C p.C1321S (on ENST00000308370 / NM_001042544.1; = p.C1284S on NM_003573.2) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52590563; called by muse, mutect2
- MAGEB18 | c.678G>C p.M226I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV57465063; called by muse, mutect2, varscan2
- MAGEL2 | c.2801G>T p.W934L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV100046228; called by muse, mutect2
- MAP2K4 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV62260708; called by muse, mutect2, varscan2
- MCM4 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs1563832980, COSV50632595; called by muse, mutect2, varscan2
- MEP1A | c.1767A>G p.I589M | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as rs1319484683, COSV57921280; called by muse, mutect2
- MMP17 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62181351; called by muse, mutect2, varscan2
- MTCL1 | c.4270G>C p.D1424H (on ENST00000306329 / NM_001378206.1; = p.D1105H on NM_015210.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60405320, COSV60411771; called by muse, mutect2, varscan2
- MYO15A | c.4870G>A p.E1624K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52753735, COSV99232642; called by muse, varscan2
- NALCN | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51964874; called by muse, mutect2, varscan2
- NIN | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755067990, COSV55385383; called by muse, mutect2, varscan2
- NLRP14 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV55067015, COSV55072330; called by muse, mutect2, varscan2
- NMNAT2 | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54271850; called by muse, mutect2, varscan2
- NR2C1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100280679; called by muse, mutect2, varscan2
- NRK | c.3698T>A p.M1233K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV54606835; called by muse, mutect2
- OR10A5 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55055716; called by muse, mutect2, varscan2
- OR10G8 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV70909426; called by muse, mutect2, varscan2
- OR11H1 | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99422029; called by muse, mutect2, varscan2
- OR2T4 | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as COSV63545141; called by muse, mutect2, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2, varscan2
- OR4K1 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53458615, COSV99579426; called by muse, mutect2
- OR4X1 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60723923; called by muse, mutect2, varscan2
- OR51E2 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67808735; called by muse, mutect2, varscan2
- OR5W2 | c.265A>G p.N89D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV60618395; called by muse, mutect2, varscan2
- OR6K6 | c.908T>A p.V303D (on ENST00000368144; = p.V279D on NM_001005184.1) | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63744899; called by muse, mutect2, varscan2
- OR8K3 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV57133123; called by mutect2, varscan2
- P2RY10 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50685911, COSV99409411; called by muse, mutect2, varscan2
- P2RY10 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409014; called by muse, mutect2, varscan2
- PAPOLG | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV53185703; called by muse, mutect2, varscan2
- PARD3B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs758241997, COSV62530504; called by mutect2, varscan2
- PCDH11X | c.1875C>G p.I625M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53503785; called by muse, mutect2, varscan2
- PDE3A | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV62982696; called by muse, mutect2, varscan2
- PDIA2 | c.1119+2T>A p.X373_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV51993304; called by muse, mutect2
- PIK3R4 | c.1711C>G p.Q571E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV63243865; called by muse, mutect2, varscan2
- PIP4K2A | c.1045A>G p.R349G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV60542667; called by muse, mutect2
- PLXNA1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV52532543; called by muse, mutect2, varscan2
- PM20D1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs1462402347, COSV65649696; called by muse, mutect2, varscan2
- POLE | c.4601A>C p.H1534P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV57690520; called by muse, mutect2
- POLE2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 27/421 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs371966509; called by muse, mutect2
- PON1 | c.428T>C p.L143S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV55933944; called by muse, mutect2
- PRDM11 | c.826C>G p.H276D (on ENST00000530656 / NM_001359633.1; = p.H242D on NM_001256695.1) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV55443718; called by muse, mutect2
- PRDM9 | c.1682T>A p.F561Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57013203; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as COSV56058435; called by pindel, varscan2
- PSAPL1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100040744; called by muse, mutect2, varscan2
- PSG8 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60615832; called by muse, mutect2
- PTGER3 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100139700; called by muse, mutect2
- PTPRT | c.2105G>C p.S702T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.211); catalogued as COSV62019758; called by muse, mutect2, varscan2
- QPCTL | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV99171342; called by muse, mutect2, varscan2
- RBL1 | c.3077A>C p.Q1026P | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60333734; called by muse, mutect2
- RBM48 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99720361; called by muse, mutect2, varscan2
- RGS22 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62667637; called by muse, mutect2, varscan2
- RHOXF1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.589); catalogued as COSV99483934; called by muse, mutect2, varscan2
- RNF213 | c.6591C>G p.C2197W | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV60408749; called by muse, mutect2, varscan2
- RUNX2 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as COSV61845892; called by muse, mutect2
- SBDS | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55888669; called by muse, mutect2, varscan2
- SCNM1 | c.33T>A p.S11R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54862031; called by muse, mutect2, varscan2
- SEMA5A | c.2215G>T p.D739Y | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66805439; called by muse, mutect2, varscan2
- SEMA5A | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754798514, COSV101227663, COSV66805444; called by muse, varscan2
- SH2D3C | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV59129575; called by muse, mutect2, varscan2
- SI | c.1826G>A p.W609* | Nonsense Mutation (SNP) | VAF 29/173 reads (17%) | catalogued as COSV52288666, COSV52300817; called by muse, mutect2, varscan2
- SIX2 | c.752del p.G251Afs*47 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as COSV57390094; called by mutect2, pindel, varscan2
- SLC16A2 | c.439G>T p.G147* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as CM090716, COSV52082451, COSV52088806; called by muse, mutect2
- SLC25A14 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54420163, COSV99502532; called by muse, mutect2
- SLC26A4 | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554555831, CM077973, COSV55920092; called by muse, mutect2, varscan2
- SLC35F5 | c.654G>C p.M218I | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99830274; called by muse, mutect2, varscan2
- SLC39A6 | c.1801A>G p.M601V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52371386; called by muse, mutect2, varscan2
- SLCO5A1 | c.2190C>A p.N730K | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV52668177; called by muse, mutect2, varscan2
- SLITRK1 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV65677595; called by muse, mutect2, varscan2
- SMARCAD1 | c.2910-1G>C p.X970_splice | Splice Site (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62776227; called by muse, mutect2, varscan2
- SMC6 | c.1427G>C p.R476P | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV61178379; called by muse, mutect2, varscan2
- SP3 | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV59471005; called by muse, mutect2, varscan2
- SPPL2C | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.267); catalogued as COSV61293719; called by muse, mutect2, varscan2
- SYNE2 | c.15478A>G p.R5160G | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59970161; called by muse, mutect2, varscan2
- TAT | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.014); catalogued as COSV63532273; called by muse, mutect2
- TCHH | c.3418T>A p.Y1140N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV64277704; called by muse, mutect2, varscan2
- TDRD10 | c.139A>T p.K47* | Nonsense Mutation (SNP) | VAF 30/156 reads (19%) | catalogued as COSV63813751; called by muse, mutect2, varscan2
- TENM1 | c.5121T>A p.Y1707* | Nonsense Mutation (SNP) | VAF 24/219 reads (11%) | catalogued as COSV64443062; called by muse, mutect2, varscan2
- TENM1 | c.3385G>C p.D1129H | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV64443073, COSV64448189; called by muse, mutect2, varscan2
- TEX15 | c.7658C>T p.S2553F (on ENST00000256246; = p.S2936F on NM_001350162.2) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs762522720, COSV56344927; called by muse, mutect2, varscan2
- THOC2 | c.4670G>T p.G1557V | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.247); catalogued as COSV99834233; called by muse, mutect2
- THOC2 | c.4669G>A p.G1557S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as COSV99834239; called by muse, mutect2
- TIMELESS | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV57515198; called by muse, mutect2, varscan2
- TMEM178A | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56143423; called by muse, mutect2, varscan2
- TMEM207 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61562306; called by muse, mutect2, varscan2
- TMEM214 | c.1387A>C p.T463P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV53194036; called by muse, mutect2
- TMF1 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV68375917; called by muse, mutect2, varscan2
- TRAM1L1 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV60293327; called by muse, mutect2, varscan2
- TRHDE | c.2232C>A p.Y744* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV53865788; called by muse, varscan2
- TRHDE | c.3072C>A p.H1024Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53865799, COSV99672663; called by muse, mutect2, varscan2
- TRIM41 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100163526; called by muse, mutect2, varscan2
- TRIM46 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.351); catalogued as COSV100104866; called by muse, mutect2, varscan2
- TRIM58 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs762790977, COSV100825210, COSV100825310; called by muse, mutect2
- TRMT1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs377647271; called by muse, mutect2, varscan2
- TRPM6 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV62522268; called by muse, mutect2, varscan2
- TSC22D1 | c.495A>T p.L165F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as COSV71776396; called by muse, mutect2, varscan2
- TSKS | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as COSV55879273; called by muse, mutect2, varscan2
- TSPAN11 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53821651; called by muse, mutect2
- TTC23L | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV72206083; called by muse, mutect2, varscan2
- TTC5 | c.1304C>A p.S435* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV51870780, COSV51871980, COSV51872245; called by muse, mutect2, varscan2
- TTN | c.86585G>C p.G28862A (on ENST00000591111; = p.G21438A on NM_003319.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV60345549; called by muse, mutect2, varscan2
- UHMK1 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV99966385; called by muse, mutect2
- UNCX | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60333667; called by muse, mutect2, varscan2
- USF2 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99723372; called by muse, mutect2, varscan2
- USH2A | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs193921072, COSV56356434, COSV56419910; called by muse, mutect2
- VN1R2 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV100448192; called by muse, mutect2, varscan2
- VPS8 | c.2932G>T p.E978* (on ENST00000625842 / NM_001349294.1; = p.E976* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99804081; called by muse, mutect2, varscan2
- VSIG10 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63654455; called by muse, mutect2
- WASF2 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV71006658; called by muse, mutect2, varscan2
- WDR36 | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV72605492; called by muse, mutect2, varscan2
- WDR72 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV64753922; called by muse, mutect2, varscan2
- ZFP1 | c.1187G>C p.S396T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100182164; called by muse, mutect2, varscan2
- ZNF420 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV58496410; called by muse, mutect2, varscan2
- ZNF449 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as COSV59348120; called by muse, mutect2, varscan2
- ZNF600 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100593114; called by muse, mutect2, varscan2
- ZNF618 | c.2522C>G p.A841G (on ENST00000374126 / NM_001318042.2; = p.A748G on NM_133374.2) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55929586; called by muse, mutect2, varscan2
- ZNF713 | c.1226G>T p.R409L (on ENST00000633730 / NM_001366796.2; = p.R422L on NM_182633.3) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV70056968; called by muse, mutect2, varscan2
- ZNF790 | c.91A>T p.R31* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV63213269; called by muse, mutect2, varscan2
- ADRA1A | c.1323del p.S442Afs*36 | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | called by mutect2, varscan2
- AP2A1 | c.2237del p.K746Sfs*90 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- ATN1 | c.1110dup p.M371Hfs*9 | Frame Shift Ins (INS) | VAF 35/169 reads (21%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); called by muse, mutect2
- MRC1 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVOL2 | c.383del p.F128Sfs*7 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.2053del p.Q685Rfs*14 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PRKX | c.802del p.D268Ifs*4 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- ABCB4 | c.54G>A p.E18= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs141141860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.783C>A p.A261= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as COSV51702476; called by muse, mutect2, varscan2
- ADAMTS15 | c.2176C>T p.L726= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs766558119, COSV54509695; called by muse, mutect2, varscan2
- ANKH | c.282G>A p.G94= | Silent (SNP) | VAF 57/114 reads (50%) | catalogued as rs760249447, COSV52484782; ClinVar: benign; called by muse, mutect2, varscan2
- ARSA | c.543C>T p.I181= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53351310; called by muse, mutect2, varscan2
- ASH1L | c.534G>A p.L178= | Silent (SNP) | VAF 47/253 reads (19%) | catalogued as COSV64213718; called by muse, mutect2, varscan2
- ASTN2 | c.3168C>T p.A1056= (on ENST00000313400 / NM_001365069.1; = p.A1005= on NM_014010.5) | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV56012835, COSV56014854; called by muse, mutect2, varscan2
- ATP6AP1 | c.1170C>A p.P390= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV63896293; called by muse, mutect2, varscan2
- C2CD5 | c.2376C>G p.V792= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100448357, COSV61727649; called by muse, mutect2, varscan2
- CD80 | c.747T>C p.I249= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV99958485; called by muse, mutect2
- CELSR1 | c.5262C>T p.H1754= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs576300546, COSV53088021; called by muse, mutect2, varscan2
- CHML | c.1596G>A p.P532= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs747736759, COSV59367386; called by muse, mutect2, varscan2
- CHRNA6 | c.570C>T p.I190= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as rs773376342, COSV99373430; called by muse, mutect2, varscan2
- CIB4 | c.15G>A p.L5= | Silent (SNP) | VAF 32/220 reads (15%) | catalogued as COSV56600743; called by muse, mutect2, varscan2
- CREBBP | c.2703G>T p.P901= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99272163; called by muse, varscan2
- CST11 | c.360T>C p.F120= (on ENST00000377009 / NM_130794.2; = p.F85= on NM_080830.3) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs548414724, COSV65441199; called by muse, mutect2, varscan2
- DGKH | c.2520C>T p.P840= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV54941800; called by muse, mutect2, varscan2
- DRC1 | c.2140C>T p.L714= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV55519566; called by muse, mutect2
- EMILIN2 | c.1431C>T p.G477= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs748210111, COSV54425830; called by muse, mutect2, varscan2
- EMILIN2 | c.1995T>C p.H665= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV54427546; called by muse, mutect2, varscan2
- FLAD1 | c.93C>T p.L31= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs1397477778, COSV52696612, COSV52700003; called by muse, mutect2, varscan2
- GABRR1 | c.345C>T p.D115= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101034124; called by muse, mutect2, varscan2
- GALNT17 | c.1305A>G p.R435= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV61191412; called by muse, mutect2
- GBP7 | c.294G>A p.T98= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs568032844, COSV54011952; called by muse, mutect2, varscan2
- GLDC | c.855G>A p.Q285= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV58685186; called by muse, mutect2, varscan2
- GPRC6A | c.891G>A p.K297= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV59955911; called by muse, varscan2
- HIVEP3 | c.600C>A p.P200= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV56023510; called by muse, mutect2
- HTR2A | c.246C>A p.A82= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs779991888, COSV101096867; called by muse, mutect2, varscan2
- IDUA | c.1746G>A p.E582= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as COSV99926482; called by muse, varscan2
- ITGAD | c.651C>A p.P217= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV66759259, COSV66760188; called by muse, mutect2, varscan2
- KATNAL1 | c.720A>G p.P240= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1277694146, COSV66064861; called by mutect2, varscan2
- KIAA2013 | c.813C>T p.N271= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV64861217; called by muse, mutect2, varscan2
- LCT | c.4446C>T p.A1482= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs148768579; called by muse, mutect2, varscan2
- LETM1 | c.1575G>A p.L525= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100245232, COSV57104458; called by muse, mutect2, varscan2
- LGALS13 | c.162C>T p.F54= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55679671; called by muse, mutect2, varscan2
- MYF6 | c.201C>A p.G67= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs762595246, COSV57352480; called by muse, mutect2, varscan2
- MYH2 | c.483C>T p.N161= | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as COSV55448254; called by muse, mutect2, varscan2
- MYH4 | c.1821T>A p.T607= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV55126178; called by muse, mutect2, varscan2
- MYLK4 | c.231C>T p.L77= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs147243450, COSV51152265; called by muse, mutect2
- NECAB2 | c.1160G>A p.*387= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as rs756128904, COSV59423410; called by muse, mutect2, varscan2
- NEU2 | c.939G>A p.P313= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs748592888, COSV52093700; called by muse, mutect2, varscan2
- NRROS | c.1242C>A p.L414= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV60745231, COSV60747786; called by muse, mutect2, varscan2
- OR4K1 | c.375C>T p.A125= | Silent (SNP) | VAF 25/232 reads (11%) | catalogued as COSV99579437; called by muse, mutect2
- OR4K15 | c.501G>C p.V167= (on ENST00000305051; = p.V143= on NM_001005486.1) | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV59303402; called by muse, mutect2
- PIK3C3 | c.1875G>T p.T625= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as COSV56284632; called by muse, mutect2, varscan2
- PREX1 | c.1524G>A p.E508= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV64256830; called by muse, mutect2, varscan2
- PREX2 | c.1284T>G p.P428= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV55798378, COSV55799273; called by muse, mutect2, varscan2
- PRPF40B | c.99C>T p.P33= (on ENST00000380281; = p.P27= on NM_012272.3) | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs1284615054, COSV56057601; called by muse, varscan2
- PTH2R | c.1398G>T p.A466= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55916958, COSV55920308; called by muse, mutect2, varscan2
- RNPS1 | c.411C>T p.S137= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV57047786; called by muse, mutect2
- RYR3 | c.7623C>T p.F2541= (on ENST00000389232; = p.F2542= on NM_001036.6) | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV66808301; called by muse, mutect2, varscan2
- SELENOV | c.879C>T p.H293= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV59064785; called by muse, mutect2, varscan2
- STON1 | c.2163C>T p.I721= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs769964189, COSV59138226; called by muse, mutect2, varscan2
- STPG1 | c.339A>G p.A113= (on ENST00000337248 / NM_001199013.2; = p.A66= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV50225047; called by muse, mutect2, varscan2
- TEC | c.468A>T p.A156= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV67406457; called by muse, mutect2, varscan2
- TLR10 | c.523A>C p.R175= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV58302332; called by muse, mutect2, varscan2
- TMEM39B | c.648C>G p.L216= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100298243; called by mutect2, varscan2
- TP63 | c.1257G>A p.E419= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV53220902; called by muse, mutect2, varscan2
- TSC2 | c.474A>G p.E158= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV54779798; called by muse, mutect2, varscan2
- UGT2B10 | c.1020G>T p.G340= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV55321696, COSV55323587; called by muse, mutect2, varscan2
- USH2A | c.9087C>T p.V3029= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV56435511; called by muse, mutect2
- WDR37 | c.321C>G p.L107= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV54131634; called by muse, mutect2
- ADGRE4P | n.1136C>A | RNA (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83100G>T | Intron (SNP) | VAF 79/284 reads (28%) | called by muse, mutect2, varscan2
- BTN2A3P | n.218C>T | RNA (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- MAGEA5 | n.3G>T | RNA (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2
- MIR129-1 | n.67G>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- SNORD109A | n.35G>T | RNA (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ZNF99 | c.*111T>C | 3'UTR (SNP) | VAF 22/74 reads (30%) | catalogued as COSV68056755; called by muse, mutect2, varscan2
